Somatic mutation profile of tumor specimen 0DT4J5 from CCDI case PBCIXY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,046 days).
Specimen 0DT4J5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d591c171-8efc-4363-b752-ad085971c290.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT4I6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac64353a-1586-431e-8a39-0e60052e40b9

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, In Frame Del 1, Frame Shift Ins 1, Silent 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B2 | c.1726G>A p.V576M (on ENST00000352432; = p.V542M on NM_001683.5) | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs759927011, COSV104416345; called by muse, mutect2, varscan2
- TPO | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777937878, COSV61102562; called by muse, varscan2
- TYMP | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 138/406 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs567858165; called by muse, mutect2, varscan2
- ZNF836 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs112435970, COSV59085515; called by muse, mutect2, varscan2
- CDKN2A | c.203_204dup p.E69Rfs*78 | Frame Shift Ins (INS) | VAF 50/148 reads (34%) | called by mutect2, varscan2
- CYB5R4 | c.455_457del p.P152_K153delinsQ | In Frame Del (DEL) | VAF 44/235 reads (19%) | called by mutect2, varscan2
- KIAA1522 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 46/159 reads (29%) | PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SORCS3 | c.1527C>T p.D509= | Silent (SNP) | VAF 85/318 reads (27%) | catalogued as rs764765132; called by muse, mutect2, varscan2
- CGB3 | c.-10C>T | 5'UTR (SNP) | VAF 69/308 reads (22%) | catalogued as rs764152129; called by muse, mutect2, varscan2
- FOXRED1 | c.417+73A>G | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
